Surgical pathology report (de-identified scan), TCGA case TCGA-IZ-A6M9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-IZ-A6M9-01A (Primary Tumor).

[page 1 of 3]
MRN
Name
Encounter Number

Gender
Date Of Birth

M

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Correction to results

Results

Correction

Source of Specimen
RIGHT RENAL MASS-NFS-

FINAL DIAGNOSIS:
RIGHT RENAL MASS-NFS-
RENAL CELL CARCINOMA, LIMITED TO RENAL TISSUE EXAMINED.

PROPORTION OF SARCOMATOID COMPONENT: 0 %.

SPECIMEN LATERALITY: RIGHT.

TUMOR FOCALITY: FOCAL.

TUMOR SIZE (LARGEST TUMOR, IF MULTIPLE): 3.8 CM.

HISTOLOGIC TYPE: PAPILLARY TYPE.

HISTOLOGIC GRADE (FUHRMAN NUCLEAR GRADE): 2/4.

TNM STAGE: pT1a, pNX, pMX.

LYMPH NODE(S) INCLUDED IN ALL PARTS: NONE EXAMINED.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

SPECIMEN TYPE: RIGHT PARTIAL NEPHRECTOMY.

SPECIMEN SIZE: 4.0 x 3.8 x 2.8 CM.

ICD-0-3
Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NOS
C64.9
JW 7/24/13

Prepared for:

[page 2 of 3]
ADRENAL GLAND: N/A.

NO TUMOR SEEN AT RESECTION MARGINS.

EVALUATION OF NON-NEOPLASTIC KIDNEY: TO BE REPORTED IN AN
ADDENDUM.

Signature

(Case signed

Signed Others

Frozen Section

RIGHT RENAL MASS (GROSS EXAM): 3.8 CM, WELL-DEFINED NODULE
LINED WITH A THIN CAPSULE, CONSISTENT WITH RENAL CELL
CARCINOMA. MARGINS ARE INKED AND APPEAR UNINVOLVED ON GROSS
EXAM.

Frozen section performed by

(Frozen Section Signed

Case Clinical Information

RIGHT RENAL MASS

Gross Description

Received in formalin labeled with the patient's name and "right
renal mass NFS" is a previously inked and serially sectioned
partial nephrectomy specimen measuring 4 x 3 x 2.8 cm. The
parenchymal margin has been inked black and the capsule margin
blue. The cut surface is remarkable for a 3.8 cm, well-defined
nodule lined by a thin capsule, consistent with renal cell
carcinoma. The margins grossly appear uninvolved.
Representative sections demonstrating mass to capsule and
parenchyma=A1-A6

Physicians

Signed Supplemental

EVALUATION OF NON-NEOPLASTIC RENAL PARENCHYMA SHOWS COMPRESSION
ATROPHY IN THE IMMEDIATE VICINITY OF THE TUMOR; THE PARENCHYMA
AT THE SURGICAL RESECTION MARGIN SHOWS MILD CHRONIC CHANGES AND
MILD VASCULAR SCLEROSIS.

Prepared for

[page 3 of 3]
JONES, PAS AND TRICHROME EXAMINED.

(Supplemental Report Signed

Procedure

- A. AA ROUTINE H&E X1 BLOCK.1
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.2
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.3
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.4
- H&E X1
- A. AA ROUTINE H&E X1 BLOCK.5
- H&E X1 JONES PAS TRICHROME
- A. AA ROUTINE H&E X1 BLOCK.6
- H&E X1

Prepared for

ILPAA Discrepancy		

Source: NCI Genomic Data Commons file 8da25b37-4574-4695-a47f-a8c066fdcaa6 (TCGA-IZ-A6M9.F492EF1F-F786-4D10-B59E-D8435F7FAAB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).